Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7327, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7327-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN TWELVE LYMPH NODES (0/12).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7, WITH A TERTIARY GLEASON GRADE 5 COMPONENT.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT SIDES OF PROSTATE AND HAS A GREATEST NODULAR DIAMETER OF 2.1 CM.
- C. THE CARCINOMA INVOLVES APPROXIMATELY 20% OF THE EXAMINED PROSTATE BY VOLUME.
- D. TUMOR SHOWS EXTRA-PROSTATIC EXTENSION AT THE RIGHT AND LEFT BASE (BLOCKS 3A, 3X, 3UU AND 3VV).
- E. BILATERAL SEMINAL VESICLES ARE INVOLVED BY CARCINOMA.
- F. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- G. EXTENSIVE PERINEURAL INVASION IS PRESENT.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS PRESENT.
- J. PATHOLOGIC TNM STAGE: pT3b N0.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 12.2
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS

PRIMARY GLEASON GRADE: 3
SECONDARY GLEASON GRADE: 4
GLEASON SUM SCORE: 7
GLEASON 4/5 PERCENTAGE: 40%
WEIGHT OF PROSTATE: 69.97gm
TUMOR SIZE: Maximum dimension: 2.1 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: 5 - 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: Yes - multifocal
EXTRAPROSTATIC EXTENSION: Yes - Multifocal
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: No
SEMINAL VESICLE INVASION: Yes
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: RX
LYMPH NODES EXAMINED: 17
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 09f0e93d-7409-4bcb-b647-466fbb1df369 (TCGA-EJ-7327.D2A2C78B-E7DD-4BDF-A6A0-4B87383A55BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).